Gene-level copy-number profile of tumor specimen TCGA-BR-A4CQ-01A from TCGA case TCGA-BR-A4CQ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.1 years (21,207 days).
Specimen TCGA-BR-A4CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9cd78c0f-31b3-4b77-981e-e3cec4596b38.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4CQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 420 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2484a71e-57e1-44fc-a9cd-78c92e494dcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 3,610; copy number 2: 22,371; copy number 3: 19,383; copy number 4: 11,115; copy number 5: 822; copy number 6: 1,751; copy number 7: 73; copy number 8: 274; copy number 9: 53; copy number 10: 75; copy number 11: 38; copy number 12: 12; copy number 13: 22; copy number 15: 19; copy number 18: 1; copy number 21: 27; copy number 22: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4CQ-01A-12D-A253-01): tumor purity 0.68, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,673,732–245,676,478, 1 gene: AC104462.1.
- chr3:857,124–1,404,217, 4 genes (within-gene range 0–1): AC090044.1, AC087430.1, RN7SL120P, CNTN6.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,198 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,489,703–82,808,021, 8 genes, copy number 5 (within-gene range 2–5): GBE1, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr3:160,677,160–165,078,496, 28 genes, copy number 5 (within-gene range 4–5): ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI.
- chr4:68,509,441–68,628,899, 5 genes, copy number 5: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.
- chr5:32,103,445–32,791,724, 15 genes, copy number 15: AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3.
- chr5:33,888,056–36,688,334, 51 genes, copy number 5–18 (within-gene range 3–18): RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2.
- chr5:36,667,717–36,669,958, 1 gene, copy number 5: AC008957.3.
- chr5:39,284,140–44,413,989, 87 genes, copy number 9–22 (broad region; genes not listed).
- chr6:28,570,535–30,494,194, 137 genes, copy number 5–10 (broad region; genes not listed).
- chr6:40,713,411–60,942,327, 360 genes, copy number 5–12 (broad region; genes not listed).
- chr7:12,211,270–19,002,416, 71 genes, copy number 6 (within-gene range 4–7) (broad region; genes not listed).
- chr7:51,716,657–54,257,577, 23 genes, copy number 5: RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1.
- chr8:12,721,906–12,756,073, 1 gene, copy number 5 (within-gene range 4–5): LONRF1.
- chr8:12,765,849–16,567,490, 38 genes, copy number 5 (within-gene range 4–5): AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2.
- chr11:13,276,652–16,739,591, 46 genes, copy number 5 (within-gene range 4–5): ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1.
- chr11:37,702,125–40,112,599, 14 genes, copy number 5: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr11:40,351,564–40,513,269, 2 genes, copy number 5: Y_RNA, AC090720.1.
- chr11:64,300,358–67,398,410, 208 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:80,653,429–80,762,826, 2 genes, copy number 5: ARL6IP1P3, LINC02720.
- chr11:81,552,226–81,556,425, 2 genes, copy number 6: MTND4LP18, MTND6P25.
- chr12:22,409,237–22,618,868, 1 gene, copy number 6 (within-gene range 2–6): AC053513.1.
- chr12:22,573,425–26,335,856, 59 genes, copy number 6–8 (within-gene range 3–8): LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3.
- chr13:18,467,172–21,704,498, 111 genes, copy number 6 (broad region; genes not listed).
- chr13:66,302,834–67,230,445, 1 gene, copy number 8 (within-gene range 4–8): PCDH9.
- chr13:66,630,715–78,910,542, 136 genes, copy number 8–21 (broad region; genes not listed).
- chr14:41,296,286–50,865,659, 133 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:62,699,464–63,318,935, 6 genes, copy number 7 (within-gene range 4–7): KCNH5, AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5.
- chr14:74,471,930–75,474,111, 40 genes, copy number 6–10 (within-gene range 2–10): AC005479.2, AC005479.1, NPC2, MIR4709, RAP1AP, ISCA2, LTBP2, AC013451.1, AC013451.2, AREL1, AC007956.2, AC007956.1, FCF1, YLPM1, PROX2, AC006530.1, DLST, RPS6KL1, PGF, EIF2B2, AL049780.1, AL049780.3, MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2.
- chr14:105,764,503–106,360,324, 102 genes, copy number 6 (broad region; genes not listed).
- chr15:52,307,283–53,764,310, 16 genes, copy number 5–9: MYO5A, EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P, RNU6-449P.
- chr15:80,059,568–101,933,350, 537 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:1,176,790–2,049,510, 8 genes, copy number 5: COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–1,929,094, 1 gene, copy number 5: AIDAP3.
- chr18:20,946,906–23,026,488, 50 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr20:30,278,906–64,313,132, 898 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,133. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
